Somatic mutation profile of tumor specimen PCProject_0013_T1_WES (aliquot PCProject_0013_T1_WES_1) from CMI case PCProject_0013, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.9 years (22,259 days).
Specimen PCProject_0013_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2625a434-f083-423d-a08a-dc60e11a1d78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0013_SALIVA (Saliva), aliquot PCProject_0013_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a115a981-b5fd-4b14-8261-8f384751e850

The open-access MAF lists 42 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Intron 13, Silent 5, 3'UTR 3, Frame Shift Del 2, 3'Flank 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.752_763del p.G251_F254del | In Frame Del (DEL) | VAF 10/76 reads (13%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ATP10A | c.1624A>T p.S542C | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs184399588; called by muse, mutect2, varscan2
- GRIK3 | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 21/205 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV66136268; called by muse, mutect2, varscan2
- RELN | c.2260C>T p.R754W | Missense Mutation (SNP) | VAF 74/220 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs759711654, COSV59024775; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCTR | c.203G>C p.G68A | Missense Mutation (SNP) | VAF 61/284 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.297); catalogued as rs1250397511, COSV50026995; called by muse, mutect2, varscan2
- SLC26A4 | c.2182dup p.Y728Lfs*26 | Frame Shift Ins (INS) | VAF 30/140 reads (21%) | catalogued as rs1554362779, CI002209, CI0910674; called by pindel, varscan2
- ZNF729 | c.1285A>G p.K429E | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as rs767999986, COSV62602887; called by mutect2, varscan2
- BEGAIN | c.140A>C p.Q47P | Missense Mutation (SNP) | VAF 106/429 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- CASZ1 | c.1220_1241delinsGGCGGCCAGGG p.P407Rfs*44 | Frame Shift Del (DEL) | VAF 43/443 reads (10%) | called by pindel, varscan2*
- COL5A2 | c.1358G>A p.G453E | Missense Mutation (SNP) | VAF 47/266 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRYBA4 | c.125A>G p.E42G | Missense Mutation (SNP) | VAF 74/470 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- HHAT | c.803A>C p.H268P | Missense Mutation (SNP) | VAF 36/278 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- MS4A4A | c.94G>T p.G32W | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, varscan2
- NOTCH1 | c.4159G>T p.A1387S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCDHGA1 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 24/498 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); called by muse, mutect2
- PLIN5 | c.1208C>G p.P403R | Missense Mutation (SNP) | VAF 68/417 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- RCOR3 | c.23A>C p.Q8P | Missense Mutation (SNP) | VAF 122/359 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBA52 | c.67A>T p.I23F | Missense Mutation (SNP) | VAF 95/353 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- ZNF646 | c.3468del p.V1158Wfs*10 | Frame Shift Del (DEL) | VAF 116/397 reads (29%) | called by mutect2, pindel, varscan2
- AC004922.1 | c.558C>T p.G186= | Silent (SNP) | VAF 79/938 reads (8%) | called by muse, mutect2
- BAG3 | c.339C>G p.V113= | Silent (SNP) | VAF 119/764 reads (16%) | called by muse, mutect2, varscan2
- PUSL1 | c.279C>G p.V93= | Silent (SNP) | VAF 18/106 reads (17%) | called by muse, mutect2, varscan2
- RBPMS | c.351T>C p.S117= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs1363708507; called by muse, mutect2, varscan2
- TBX22 | c.882T>A p.L294= | Silent (SNP) | VAF 18/105 reads (17%) | called by muse, mutect2, varscan2
- ACTA2 | c.617-43G>A | Intron (SNP) | VAF 15/82 reads (18%) | catalogued as rs200057287; called by muse, mutect2, varscan2
- ADGRL3 | chr4:62071755 G>A | 3'Flank (SNP) | VAF 10/44 reads (23%) | catalogued as rs149131531; called by mutect2, varscan2
- AL138759.1 | n.208-2799A>G | Intron (SNP) | VAF 14/115 reads (12%) | catalogued as rs1413802823; called by muse, varscan2
- CACNA1G | c.4422+151G>A | Intron (SNP) | VAF 43/299 reads (14%) | catalogued as rs747883982, COSV100661084; called by muse, mutect2, varscan2
- CNGA1 | c.-15+10490T>G | Intron (SNP) | VAF 12/104 reads (12%) | catalogued as rs1197725004, COSV104422602; called by muse, mutect2
- DNAAF1 | c.1030+15G>T | Intron (SNP) | VAF 148/778 reads (19%) | catalogued as COSV57577126; called by muse, varscan2
- DNAJC19 | c.*690A>G | 3'UTR (SNP) | VAF 7/52 reads (13%) | catalogued as rs1370714837, COSV104423365; called by muse, mutect2
- ICA1 | c.804+165_804+166insCTTTCTTTCTTT | Intron (INS) | VAF 3/99 reads (3%) | called by mutect2, varscan2*
- MATR3 | c.*1448A>G | 3'UTR (SNP) | VAF 8/53 reads (15%) | catalogued as rs1298787056; called by muse, mutect2
- PTPN18 | c.414+2592A>G | Intron (SNP) | VAF 11/86 reads (13%) | catalogued as rs1254023457, COSV51558883; called by muse, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 21/331 reads (6%) | catalogued as rs910081914; called by muse, mutect2
- SLC30A4 | c.391+987T>G | Intron (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- STAB1 | c.4364-30C>T | Intron (SNP) | VAF 25/141 reads (18%) | called by muse, mutect2, varscan2
- TMEM67 | chr8:93819062 A>C | 3'Flank (SNP) | VAF 20/334 reads (6%) | called by muse, mutect2
- XPO5 | c.2678-356T>C | Intron (SNP) | VAF 38/252 reads (15%) | catalogued as rs1242378776, COSV54830476; called by muse, varscan2
- YIPF3 | c.395+329G>T | Intron (SNP) | VAF 41/531 reads (8%) | catalogued as rs1383044718, COSV104411955; called by muse, mutect2
- ZCWPW2 | c.493-458A>G | Intron (SNP) | VAF 10/159 reads (6%) | called by muse, mutect2
- ZNF714 | c.*815A>G | 3'UTR (SNP) | VAF 16/258 reads (6%) | catalogued as rs1158296799; called by muse, mutect2
